Somatic mutation profile of tumor specimen HTMCP-03-06-02380-01A (aliquot HTMCP-03-06-02380-01A-01D-10409) from CGCI case HTMCP-03-06-02380, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G4; Age at diagnosis: 59.6 years (21,753 days).
Specimen HTMCP-03-06-02380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 243ea011-68db-47c7-b4c5-e3086ee0fe21.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02380-10A (Blood Derived Normal), aliquot HTMCP-03-06-02380-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/812efb6f-9c84-4dea-b972-d0a9d0b549ed

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2, Translation Start Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV99370301; called by muse, mutect2
- FBXO40 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57523897; called by muse, mutect2, varscan2
- ITGB3 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs1282245056, COSV71384792; called by muse, mutect2, varscan2
- LRP2 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV55554701; called by muse, mutect2, varscan2
- CMYA5 | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- DPP10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/215 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2
- EP300 | c.4196del p.D1399Vfs*11 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel*, varscan2
- PCNX3 | c.5039C>T p.S1680L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by mutect2, varscan2
- ZMYND8 | c.2971G>T p.E991* (on ENST00000311275 / NM_001363741.2; = p.E965* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- MBD5 | c.2742G>A p.L914= | Silent (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- PCNX3 | c.4941C>G p.L1647= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- UVRAG | c.1146C>G p.L382= | Silent (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- ZYG11A | c.1863A>T p.A621= | Silent (SNP) | VAF 69/322 reads (21%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6245G>A | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
